Somatic mutation profile of tumor specimen TARGET-20-PARJYP-03A (aliquot TARGET-20-PARJYP-03A-01D) from TARGET case TARGET-20-PARJYP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.9 years (5,433 days).
Specimen TARGET-20-PARJYP-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2270ce4e-8f89-4134-a814-a76b07aa8687.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARJYP-14A (Bone Marrow Normal), aliquot TARGET-20-PARJYP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/339db66a-3e86-46fa-9f06-2be42a370199

The open-access MAF lists 16 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 9, Missense Mutation 5, Silent 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>T p.D816Y | Missense Mutation (SNP) | VAF 134/347 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AFF3 | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 105/225 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as rs1234408099; called by muse, mutect2, varscan2
- ATM | c.4365T>A p.S1455R | Missense Mutation (SNP) | VAF 99/190 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs527471560, COSV99592662; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- FLNB | c.2660C>T p.P887L | Missense Mutation (SNP) | VAF 134/294 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as rs753985242, COSV55884411; called by muse, mutect2, varscan2
- KMT2C | c.10765C>G p.L3589V | Missense Mutation (SNP) | VAF 118/258 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs201649535, COSV51516566; called by muse, mutect2, varscan2
- INTS1 | c.2754T>C p.A918= | Silent (SNP) | VAF 64/150 reads (43%) | called by muse, mutect2, varscan2
- AXL | c.*745T>A | 3'UTR (SNP) | VAF 149/288 reads (52%) | called by muse, mutect2, varscan2
- ILF3 | chr19:10691945 G>A | 3'Flank (SNP) | VAF 129/269 reads (48%) | called by muse, mutect2, varscan2
- LPP | c.*1175C>T | 3'UTR (SNP) | VAF 204/451 reads (45%) | catalogued as rs572815937; called by muse, mutect2, varscan2
- NALCN | c.*1282_*1330delinsTTATAATCTATTTTTCTCTATTTAACATTCCTCAGATAGATAGGCAAAT | 3'UTR (ONP) | VAF 40/252 reads (16%) | called by pindel, varscan2*
- NF1 | c.*871_*873del | 3'UTR (DEL) | VAF 63/134 reads (47%) | catalogued as rs1269038642; called by mutect2, pindel, varscan2
- PPP3R1 | c.*1921C>T | 3'UTR (SNP) | VAF 101/196 reads (52%) | catalogued as rs989884853; called by muse, mutect2, varscan2
- PTEN | c.*1386A>G | 3'UTR (SNP) | VAF 117/247 reads (47%) | catalogued as rs1041217197; called by muse, mutect2, varscan2
- SMARCA5 | c.*1541T>C | 3'UTR (SNP) | VAF 209/393 reads (53%) | catalogued as rs970879928; called by muse, mutect2, varscan2
- TTC23 | c.*1157C>T | 3'UTR (SNP) | VAF 153/319 reads (48%) | catalogued as rs189062245; called by muse, varscan2
- TTLL12 | c.*1380_*1382dup | 3'UTR (INS) | VAF 46/98 reads (47%) | catalogued as rs1216340585; called by mutect2, pindel, varscan2
